Surgical pathology report (de-identified scan), TCGA case TCGA-55-6984, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-6984-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]
[REDACTED]
Patient
MRN
DOB
Date of Service
Performing Facility
Ordering Provider
Result Provider
Report Name
Status

[REDACTED] DXSTIC X

[REDACTED]
SEE REPORT

SURGICAL PATHOLOGY REPORT

PROCEDURE DATE: [REDACTED]

==== SPECIMEN DESCRIPTION: =====

- A. INFERIOR PULMONARY LIGAMENT LYMPH NODE
- B. SUBCARINAL LYMPH NODE
- C. HILAR LYMPH NODES
- D. PULMONARY ARTERY LYMPH NODE, N1
- E. PROXIMAL BRONCHIAL LYMPH NODE
- F. LEFT LOWER LOBE OF LUNG, FPC
- G. AP WINDOW LYMPH NODE

==== PRE-OPERATIVE DIAGNOSIS: =====

Lung cancer

==== POST-OPERATIVE DIAGNOSIS: =====

Same, pending pathology

==== CLINICAL INFORMATION: =====

Left lower lobe mass, cavitory

==== INTRAOPERATIVE CONSULTATION: =====

FPC DIAGNOSIS: "Received is a lobe of lung with large palpable mass; (cross section) gray-white wedge-shaped subpleural mass with mucoid cut sections; (cytosmear) non-small cell carcinoma with bronchoalveolar features, pending pathology review; small portion for tumor study" by [REDACTED]

==== GROSS DESCRIPTION: =====

- A. Received is a 1.0 x 1.0 x 0.2 cm encapsulated hyperpigmented lymph node. The specimen is bisected and totally submitted in one cassette.
- B. Received is a 1.7 x 1.7 x 0.4 cm hyperpigmented lymph node. Sectioning reveals a fleshy tan-brown cut surface. The specimen is bisected and totally submitted in one cassette.
- C. Received are two tan-brown hyperpigmented lymph nodes, measuring 0.4 x 0.4 x 0.2 cm and 0.5 x 0.4 x 0.2 cm. Both fragments are wrapped in lens paper and totally submitted in one cassette.
- D. Received is a 0.7 x 0.4 x 0.3 cm tan-brown lymph node. Sectioning reveals a fleshy cut surface. The specimen is wrapped in lens paper and totally submitted in one cassette.
- E. Received is a 1.0 x 0.8 x 0.3 cm shaggy portion of brown-black lymphoid tissue. The specimen is bisected and totally submitted in one cassette.
- F/FPC. Received is a lobe of lung, weighing 255 grams and measuring 20.3 x

[page 2 of 3]
[REDACTED]

Patient

MRN

DOB

Date of Service

Performing Facility

Ordering Provider

Result Provider

Report Name

Status

Requested by: [REDACTED]

Surgical Report

DXSTIC X

12.0 x 5.6 cm. The lung has been previously sectioned during pathology consultation. There are two transverse staple lines, located on the inferior and superior aspects of the hilum, measuring 2.8 cm and 2.5 cm. The pleural surface is tan-pink with scattered anthracotic pigmentation. The pleural surface is inked black. The lung is serially sectioned to reveal an ill-defined, hemorrhagic, focally friable, and disrupted tumor, measuring 4.5 x 3.5 x 3.5 cm. The solid portion of the tumor is yellow and firm. The tumor extends to the overlying pleural surface; however, the tumor does not disrupt the pleural surface. The lesion is located 1.0 cm from the bronchial margin. The bronchial tree is dissected to reveal a moderate amount of mucus. The arterial tree is dissected to reveal minimal fatty streaks. The remaining cut surface is pink-red, bright, and spongy, with viable parenchyma. There are nine gray-black possible lymph nodes surrounding the bronchial and arterial trees, ranging from 0.4 to 0.8 cm in greatest dimension. Representative sections are submitted in eight cassettes as follows: cassette 1 - staple line margin; cassette 2 - vascular and bronchial margins; cassette 3 - lesion at pleural surface; cassettes 4 and 5 - additional lesion; cassettes 6 and 7 - possible lymph nodes (each section represents one lymph node); cassette 8 - random normal lung parenchyma. G. Received is a 1.3 x 1.1 x 0.6 cm hyperpigmented lymph node. Sectioning reveals a glistening black cut surface. The specimen is bisected and totally submitted in one cassette.

===== MICROSCOPIC DESCRIPTION: =====

A - G. A total of fourteen slides are examined. Sections from the grossly described 4.5 cm tumor mass show moderately differentiated adenocarcinoma. The carcinoma at one point is less than 0.1 cm to the pleural surface, however, the inked surface is free of tumor. Lymphovascular invasion is seen. A few tumor nests are seen around the main tumor mass. Bronchial and vascular resection margins are negative for carcinoma. Two of the hilar lymph nodes (slide F/FPC-7) are positive for metastatic carcinoma. Other findings are listed in the diagnosis.

===== SPECIAL STAINS: =====

Well controlled immunohistochemical stains were performed. The results for the tumor cells are as follows:

CK7 positive
CK20 negative
TTF-1 very focally positive

[page 3 of 3]
Patient
MRN
DOB
Date of Service
Performing Facility
Ordering Provider
Result Provider
Report Name
Status

==== FINAL DIAGNOSIS: =====

- A. INFERIOR PULMONARY LIGAMENT LYMPH NODE, BIOPSY: ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1)
- B. SUBCARINAL LYMPH NODE, BIOPSY: ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1)
- C. HILAR LYMPH NODES, BIOPSY: TWO LYMPH NODES, NEGATIVE FOR CARCINOMA (0/2)
- D. PULMONARY ARTERY LYMPH NODE, N1, BIOPSY: ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1)
- E. PROXIMAL BRONCHIAL LYMPH NODE, BIOPSY: ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1)
- F/FPC. LEFT LOWER LOBE OF LUNG, RESECTION:
- 1. HISTOLOGIC TYPE: ADENOCARCINOMA
- 2. HISTOLOGIC GRADE: G2 (MODERATELY DIFFERENTIATED)
- 3. EXTENT OF INVASION: pT2 (TUMOR MASS GROSSLY MEASURES 4.5 X 3.5 X 3.5 CM)
- 4. MARGINS: BRONCHIAL AND VASCULAR RESECTION MARGINS AND PLEURAL SURFACE ARE NEGATIVE FOR CARCINOMA
- 5. LYMPHOVASCULAR INVASION: FOCALLY POSITIVE
- 6. REGIONAL LYMPH NODES: TWO OF NINE PERIBRONCHIAL LYMPH NODES, POSITIVE FOR METASTATIC CARCINOMA (2/9)
- 7. DISTANT METASTASIS: CANNOT BE ASSESSED
- G. A-P WINDOW LYMPH NODE, BIOPSY: ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1)

A-MALIGNANT

Source: NCI Genomic Data Commons file b2b6d90f-0b80-4342-a9ca-d022a424ed24 (TCGA-55-6984.361307D6-AEBB-446B-B06F-41C71DEAB5D2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).